Somatic mutation profile of tumor specimen C3L-07990-03 (aliquot CPT0513210006) from CPTAC case C3L-07990, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 76.3 years (27,857 days).
Specimen C3L-07990-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e8ba5c4-816d-4c7f-8646-d9c43ffccec2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07990-31 (Blood Derived Normal), aliquot CPT0513340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4f016a6-7e50-4760-86a3-8d17058be272

The open-access MAF lists 1,837 somatic variants for this specimen: 1,318 protein-altering or splice-affecting, 447 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 948, Silent 447, Frame Shift Del 209, Frame Shift Ins 64, Nonsense Mutation 60, Intron 35, In Frame Del 15, Splice Region 13, 5'UTR 10, 3'UTR 10, 5'Flank 8, Splice Site 8.

Variants (750 of 1,837; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIN1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 36/484 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1249621033, COSV52117149; ClinVar: likely pathogenic; called by muse, mutect2
- CASR | c.2152C>T p.R718W (on ENST00000490131; = p.R795W on NM_000388.4) | Missense Mutation (SNP) | VAF 37/478 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909258, CD076766, CM930079; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- COL1A2 | c.2314G>A p.G772S | Missense Mutation (SNP) | VAF 94/440 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs72658185, CM973120; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.1074del p.G359Efs*115 | Frame Shift Del (DEL) | VAF 56/242 reads (23%) | catalogued as rs104886095; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL7A1 | c.6005G>A p.R2002H | Missense Mutation (SNP) | VAF 207/578 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768326843, COSV60395911; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- DOK7 | c.1143del p.E382Sfs*74 | Frame Shift Del (DEL) | VAF 238/693 reads (34%) | catalogued as rs606231132, CX084342; ClinVar: pathogenic; called by mutect2, varscan2
- FBN1 | c.2581C>T p.R861* | Nonsense Mutation (SNP) | VAF 20/412 reads (5%) | catalogued as rs140583, CM972802, COSV57319926; ClinVar: pathogenic; called by muse, mutect2
- GRHPR | c.154del p.A52Pfs*56 | Frame Shift Del (DEL) | VAF 137/530 reads (26%) | catalogued as rs751101495; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KCNQ2 | c.1160del p.P387Rfs*2 (on ENST00000359125 / NM_172107.4; = p.P377Rfs*2 on NM_004518.6) | Frame Shift Del (DEL) | VAF 148/440 reads (34%) | catalogued as rs796052657, COSV60542103; ClinVar: pathogenic; called by mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 62/302 reads (21%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTPN11 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 84/261 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121918457, CM021672, COSV61005439; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SETX | c.4816C>T p.R1606* | Nonsense Mutation (SNP) | VAF 22/186 reads (12%) | catalogued as rs759213174, CM095656; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCB1 | c.992G>A p.R331H (on ENST00000263121; = p.R377H on NM_003073.5) | Missense Mutation (SNP) | VAF 70/695 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs387906812, CM122478, COSV51954090, COSV51954233, COSV51954740; ClinVar: uncertain significance / pathogenic; called by muse, mutect2
- SPG7 | c.1032dup p.G345Rfs*44 (on ENST00000268704; = p.G352Rfs*44 on NM_003119.4) | Frame Shift Ins (INS) | VAF 161/531 reads (30%) | catalogued as rs760818649; ClinVar: pathogenic; called by mutect2, varscan2
- SPTA1 | c.5195A>C p.K1732T | Missense Mutation (SNP) | VAF 43/159 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370558180, COSV100934623, COSV100935599; called by muse, mutect2, varscan2
- TGFBR2 | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 139/410 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs727504421, CM064328, CM139809, COSV55448438, COSV55452463; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TRNT1 | c.1252del p.S418Vfs*11 | Frame Shift Del (DEL) | VAF 24/130 reads (18%) | catalogued as rs876661298, CM1411168, COSV51642664; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ABCA12 | c.3782C>T p.S1261F (on ENST00000272895 / NM_173076.3; = p.S943F on NM_015657.3) | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs751192243; called by muse, mutect2, varscan2
- ABCA5 | c.993A>T p.E331D | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.551); catalogued as COSV67016910; called by muse, mutect2, varscan2
- ABCB10 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs1412540310, COSV60622067; called by muse, mutect2
- ABCC1 | c.3123del p.I1042Sfs*20 | Frame Shift Del (DEL) | VAF 66/655 reads (10%) | catalogued as COSV100578457; called by mutect2, pindel
- ABCF3 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 170/494 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs748060492, COSV99490492; called by muse, mutect2, varscan2
- ABHD16B | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 34/716 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV53862829; called by muse, mutect2
- ABHD4 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 103/314 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as rs756852665; called by muse, mutect2, varscan2
- ABLIM1 | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs769723095, COSV99522016; called by muse, mutect2, varscan2
- AC109583.1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 192/571 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs768769548, COSV59350985; called by muse, mutect2, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | catalogued as rs757016425; called by mutect2, varscan2
- ACLY | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 107/438 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs782018591, COSV61249391; called by muse, mutect2, varscan2
- ACSL3 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as rs149372861; called by muse, mutect2, varscan2
- ACSM4 | c.921C>T p.D307= | Splice Region (SNP) | VAF 86/215 reads (40%) | catalogued as rs747122297, COSV68069807; called by muse, mutect2, varscan2
- ACSM5 | c.701C>T p.T234I | Missense Mutation (SNP) | VAF 151/423 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1411118164; called by muse, mutect2, varscan2
- ACTN4 | c.2311C>T p.R771W | Missense Mutation (SNP) | VAF 98/377 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234222656, COSV53143783; called by muse, mutect2, varscan2
- ACTR1B | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 118/374 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs372634354; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 80/130 reads (62%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS5 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 48/682 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.334); catalogued as COSV53185072; called by muse, mutect2
- ADAMTS7 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 171/517 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs779106084; called by muse, mutect2, varscan2
- ADCY8 | c.2360T>C p.V787A | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.107); catalogued as COSV53925188; called by muse, mutect2, varscan2
- ADD3 | c.1924C>T p.L642F (on ENST00000356080 / NM_001320591.2; = p.L610F on NM_001121.4) | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs529505409; called by muse, mutect2, varscan2
- ADGRL1 | c.1685G>A p.R562Q (on ENST00000340736 / NM_001008701.3; = p.R557Q on NM_014921.5) | Missense Mutation (SNP) | VAF 132/505 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as rs767170139; called by muse, mutect2, varscan2
- AFAP1L2 | c.1837G>A p.V613I | Missense Mutation (SNP) | VAF 116/485 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs760017215, COSV58412622; called by muse, mutect2, varscan2
- AFF3 | c.623G>A p.S208N | Missense Mutation (SNP) | VAF 176/517 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.306); catalogued as COSV100418556; called by muse, mutect2, varscan2
- AKAP5 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs758946070, COSV57742121; called by muse, mutect2, varscan2
- AKAP8 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 166/615 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.398); catalogued as rs12983369; called by muse, mutect2, varscan2
- AKNA | c.2680G>A p.G894S | Missense Mutation (SNP) | VAF 27/616 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.685); catalogued as rs760033051; called by muse, mutect2
- AKR1C1 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 125/406 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as rs781973844; called by muse, mutect2, varscan2
- AMIGO3 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 135/595 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.025); catalogued as rs527254009; called by muse, mutect2, varscan2
- AMY2A | c.113A>C p.D38A | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1267450005; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7177G>A p.A2393T | Missense Mutation (SNP) | VAF 107/320 reads (33%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.024); catalogued as rs754457986, COSV99781812; called by muse, mutect2, varscan2
- ANO7 | c.173G>A p.R58Q (on ENST00000274979; = p.R4Q on NM_001001666.4) | Missense Mutation (SNP) | VAF 88/357 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1381845912, COSV51471322; called by muse, mutect2, varscan2
- AOC2 | c.821A>T p.E274V | Missense Mutation (SNP) | VAF 166/491 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV99513511; called by muse, mutect2, varscan2
- AP2M1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 28/487 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.113); catalogued as rs1299055414; called by muse, mutect2
- APBB1 | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 43/536 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs980479781, COSV54966272; called by muse, mutect2
- APBB2 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 115/467 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768003818; called by muse, mutect2, varscan2
- APC2 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 44/674 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.727); catalogued as rs868015908; called by muse, mutect2
- ARHGEF17 | c.3856C>T p.R1286W | Missense Mutation (SNP) | VAF 93/412 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55231327; called by muse, varscan2
- ARHGEF28 | c.2209G>A p.V737M | Missense Mutation (SNP) | VAF 94/364 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs190429636, COSV55272031; called by muse, mutect2, varscan2
- ARHGEF35 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs1364676967; called by mutect2, varscan2
- ARHGEF40 | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 209/601 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs757893683, COSV53879341; called by muse, mutect2, varscan2
- ARID1A | c.1015del p.A339Lfs*24 | Frame Shift Del (DEL) | VAF 264/744 reads (35%) | catalogued as rs1232964733; called by mutect2, varscan2
- ARSF | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 137/389 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145601573; called by muse, mutect2, varscan2
- ASAP3 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 133/396 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs759918483, COSV60878155; called by muse, mutect2, varscan2
- ASB10 | c.1052G>A p.R351Q (on ENST00000420175 / NM_001142459.2; = p.R336Q on NM_080871.4) | Missense Mutation (SNP) | VAF 179/706 reads (25%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.874); catalogued as rs898913097; called by muse, mutect2, varscan2
- ASB2 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.974); catalogued as rs368314093; called by muse, mutect2, varscan2
- ASTN2 | c.1651C>T p.R551C (on ENST00000313400 / NM_001365069.1; = p.R500C on NM_014010.5) | Missense Mutation (SNP) | VAF 81/373 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776841753, COSV57773431; called by muse, mutect2, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 85/262 reads (32%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATG2A | c.1993C>T p.R665W | Missense Mutation (SNP) | VAF 137/597 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1378735941, COSV65966344; called by muse, mutect2, varscan2
- ATN1 | c.1275del p.K426Sfs*27 | Frame Shift Del (DEL) | VAF 118/512 reads (23%) | catalogued as rs782523332; called by mutect2, pindel, varscan2
- ATP2B2 | c.947C>T p.A316V (on ENST00000352432; = p.A327V on NM_001001331.4) | Missense Mutation (SNP) | VAF 86/399 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.312); catalogued as rs149708084, COSV59508064; called by muse, mutect2, varscan2
- ATP8B3 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 50/492 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs567130127; called by muse, mutect2
- ATXN7 | c.1738C>T p.R580W | Missense Mutation (SNP) | VAF 89/272 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs745544193; called by muse, mutect2, varscan2
- B3GAT2 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 64/274 reads (23%) | catalogued as rs750513549, COSV100017508, COSV57769997, COSV57775208; called by muse, mutect2, varscan2
- B4GALT7 | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 112/492 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99219151; called by muse, mutect2, varscan2
- BABAM1 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 164/472 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs575115485, COSV63921635; called by muse, varscan2
- BACH1 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1295914538, COSV99728682; called by muse, mutect2, varscan2
- BACH2 | c.1570T>G p.S524A | Missense Mutation (SNP) | VAF 214/640 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV57607634; called by muse, mutect2, varscan2
- BAHCC1 | c.4541C>T p.A1514V | Missense Mutation (SNP) | VAF 119/417 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); catalogued as rs1294495291, COSV57026991; called by muse, mutect2, varscan2
- BAHCC1 | c.7477C>T p.R2493W | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs782115319; called by muse, mutect2
- BARHL2 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 76/364 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100966105; called by muse, mutect2, varscan2
- BCR | c.3269G>A p.R1090H | Missense Mutation (SNP) | VAF 124/436 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100006556; called by muse, varscan2
- BEND7 | c.14del p.K5Sfs*6 | Frame Shift Del (DEL) | VAF 68/236 reads (29%) | catalogued as rs1564375189; called by mutect2, pindel, varscan2
- BICRAL | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs113238307; called by muse, mutect2
- BLVRA | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 68/392 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs775030116; called by muse, mutect2, varscan2
- BMP5 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 72/306 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.793); catalogued as rs770622652; called by muse, mutect2, varscan2
- BOLL | c.154T>A p.F52I | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.823); catalogued as rs750907998, COSV56574030; called by muse, mutect2, varscan2
- BRSK1 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 21/654 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.692); catalogued as COSV100473547; called by muse, mutect2
- BSN | c.10718C>T p.A3573V | Missense Mutation (SNP) | VAF 89/292 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99609865; called by muse, varscan2
- BSND | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 173/570 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs368725660; called by muse, mutect2, varscan2
- BTBD11 | c.677C>A p.A226E | Missense Mutation (SNP) | VAF 228/741 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1344773836; called by muse, mutect2, varscan2
- BTNL8 | c.118T>G p.C40G | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51457700; called by muse, mutect2
- C11orf87 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 195/323 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); catalogued as rs368815365; called by muse, mutect2, varscan2
- C14orf39 | c.1762del p.*588Efs*16 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | catalogued as rs780875081; called by mutect2, varscan2
- C2orf72 | c.531del p.V179Cfs*47 | Frame Shift Del (DEL) | VAF 88/372 reads (24%) | catalogued as rs932860950; called by mutect2, varscan2
- C7orf50 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 117/655 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754169086; called by muse, mutect2, varscan2
- CABLES2 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 207/658 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs370103781; called by muse, mutect2
- CACFD1 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 36/566 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs587721079, COSV52469118; called by muse, mutect2
- CACNA1G | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 88/455 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs775209826; called by muse, mutect2, varscan2
- CACNA1H | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 146/447 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.665); catalogued as rs1188405884; called by muse, mutect2, varscan2
- CACNA2D1 | c.3181G>A p.D1061N (on ENST00000356253 / NM_001366867.1; = p.D1049N on NM_000722.4) | Missense Mutation (SNP) | VAF 10/231 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV104417633; called by muse, mutect2
- CACNG2 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 192/598 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs1292241207; called by muse, mutect2, varscan2
- CALML4 | c.229A>G p.M77V | Missense Mutation (SNP) | VAF 114/449 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs779125634, COSV61205858; called by muse, mutect2, varscan2
- CAMSAP1 | c.4625C>T p.T1542M | Missense Mutation (SNP) | VAF 87/506 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs570458407, COSV56728478; called by muse, mutect2, varscan2
- CAMTA1 | c.4723A>G p.I1575V | Missense Mutation (SNP) | VAF 120/338 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs1378784500; called by muse, mutect2, varscan2
- CAPRIN2 | c.2479C>T p.R827W | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs747429030, COSV51830499; called by muse, mutect2, varscan2
- CAPZA2 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.099); catalogued as rs1269192002, COSV63266391; called by muse, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 13/124 reads (10%) | catalogued as rs765105588; called by mutect2, varscan2
- CAT | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.124); catalogued as rs755990702; called by muse, mutect2, varscan2
- CATSPERD | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as rs1475011855, COSV67534362; called by muse, mutect2
- CCDC102A | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 149/660 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs753692091; called by muse, varscan2
- CCDC124 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 168/539 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758381298; called by muse, mutect2, varscan2
- CCDC183 | c.317T>C p.M106T | Missense Mutation (SNP) | VAF 28/607 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1429447493; called by muse, mutect2
- CCDC184 | c.182T>C p.M61T | Missense Mutation (SNP) | VAF 240/646 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs1395028668; called by muse, mutect2, varscan2
- CCDC54 | c.243C>A p.F81L | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99660110; called by muse, mutect2, varscan2
- CCDC63 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 110/366 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs775890946, COSV57531110; called by muse, mutect2, varscan2
- CCDC74A | c.385G>T p.G129* | Nonsense Mutation (SNP) | VAF 129/944 reads (14%) | catalogued as COSV54606335; called by muse, mutect2, varscan2
- CCDC85C | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 124/336 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as rs377060982; called by muse, mutect2, varscan2
- CCT8L2 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 162/540 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV63462548; called by muse, mutect2, varscan2
- CCZ1B | c.1370del p.N457Mfs*4 | Frame Shift Del (DEL) | VAF 65/214 reads (30%) | catalogued as rs777044936; called by mutect2, pindel, varscan2
- CD6 | c.52C>T p.H18Y | Missense Mutation (SNP) | VAF 192/299 reads (64%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.193); catalogued as rs770195748; called by muse, mutect2, varscan2
- CD6 | c.631C>A p.L211M | Missense Mutation (SNP) | VAF 56/686 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.763); catalogued as COSV100532803; called by muse, mutect2
- CD81 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 221/334 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as rs746119080; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD93 | c.943dup p.A315Gfs*34 | Frame Shift Ins (INS) | VAF 170/532 reads (32%) | catalogued as rs747115137; called by mutect2, varscan2
- CDH23 | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 187/637 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.314); catalogued as rs779133533; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH7 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 99/271 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761037837, COSV59884438; called by muse, mutect2, varscan2
- CDIP1 | c.20del p.P7Lfs*29 | Frame Shift Del (DEL) | VAF 179/569 reads (31%) | catalogued as COSV99566654; called by mutect2, pindel, varscan2
- CEACAM16 | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 182/541 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs757947092, COSV69186217, COSV69188149; called by muse, mutect2, varscan2
- CELSR2 | c.2210C>T p.T737M | Missense Mutation (SNP) | VAF 30/576 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs938856010, COSV99603183; called by muse, mutect2
- CEMIP | c.540dup p.E181* | Frame Shift Ins (INS) | VAF 82/277 reads (30%) | catalogued as rs753314096; called by mutect2, varscan2
- CEMIP2 | c.3815G>A p.R1272H | Missense Mutation (SNP) | VAF 78/364 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs185936154, COSV65487841; called by muse, varscan2
- CEP290 | c.1359G>A p.S453= | Splice Region (SNP) | VAF 27/99 reads (27%) | catalogued as rs779195306, COSV58350973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CFAP43 | c.2738G>A p.R913H | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs755312187, COSV99530965; called by muse, mutect2
- CFAP61 | c.2248G>A p.A750T | Missense Mutation (SNP) | VAF 48/487 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.23); catalogued as COSV99844227; called by muse, mutect2
- CHADL | c.989T>G p.V330G | Missense Mutation (SNP) | VAF 44/834 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1197395206; called by muse, mutect2
- CHAF1B | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 88/320 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as COSV58439304; called by muse, mutect2, varscan2
- CHD1 | c.3960del p.E1321Kfs*22 | Frame Shift Del (DEL) | VAF 33/120 reads (28%) | catalogued as rs1561489348; called by mutect2, pindel, varscan2
- CHIT1 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 91/347 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs568595374; called by muse, mutect2, varscan2
- CHRD | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 74/880 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs563125930; called by muse, mutect2
- CHST1 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 237/703 reads (34%) | catalogued as rs748586532, COSV57322825; called by muse, mutect2, varscan2
- CHST2 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 198/646 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs748828245; called by muse, varscan2
- CHST2 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 88/297 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV58885741; called by muse, mutect2, varscan2
- CHST7 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 34/851 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV99333053; called by muse, mutect2
- CHST8 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 50/647 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV52858516; called by muse, mutect2
- CIT | c.3515G>A p.R1172H | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs202089378; called by muse, mutect2, varscan2
- CLIC5 | c.692C>T p.P231L (on ENST00000185206 / NM_001370649.1; = p.P72L on NM_016929.5) | Missense Mutation (SNP) | VAF 176/277 reads (64%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.8); catalogued as rs147816908; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | catalogued as rs369752219; called by mutect2, varscan2
- CLSTN1 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 29/305 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs1323092498; called by muse, mutect2
- CLVS2 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 123/377 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV51559773; called by muse, varscan2
- CNTN2 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 113/372 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs767528359; called by muse, mutect2, varscan2
- CNTN3 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as rs148089886; called by muse, mutect2, varscan2
- CNTN6 | c.1726C>T p.L576F | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as rs759904703; called by muse, mutect2, varscan2
- CNTNAP4 | c.1359G>A p.W453* | Nonsense Mutation (SNP) | VAF 24/246 reads (10%) | catalogued as COSV100270029; called by muse, mutect2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 38/142 reads (27%) | catalogued as rs748995811; called by mutect2, varscan2
- COL19A1 | c.2464C>T p.R822* | Nonsense Mutation (SNP) | VAF 20/86 reads (23%) | catalogued as rs1264028087, COSV59571840; called by muse, mutect2, varscan2
- COL20A1 | c.3026C>T p.T1009M | Missense Mutation (SNP) | VAF 226/690 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs200056990, COSV100491036; called by muse, mutect2, varscan2
- COL22A1 | c.4104G>A p.P1368= | Splice Region (SNP) | VAF 95/275 reads (35%) | catalogued as rs769862699, COSV57325231, COSV57342318; called by muse, mutect2, varscan2
- COL5A1 | c.3899G>C p.G1300A | Missense Mutation (SNP) | VAF 34/782 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100880787; called by muse, mutect2
- COL6A2 | c.2711C>T p.A904V | Missense Mutation (SNP) | VAF 162/575 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs376665722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.6826G>A p.G2276R | Missense Mutation (SNP) | VAF 74/298 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761156771, COSV55081860; called by muse, varscan2
- COL6A3 | c.4031C>T p.S1344L | Missense Mutation (SNP) | VAF 117/413 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs777759049, COSV55081337; called by muse, mutect2, varscan2
- COL6A5 | c.2481del p.K827Nfs*7 | Frame Shift Del (DEL) | VAF 69/199 reads (35%) | catalogued as rs1222064379; called by mutect2, pindel, varscan2
- COL6A6 | c.5747G>T p.G1916V | Missense Mutation (SNP) | VAF 10/263 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62019770; called by muse, mutect2
- COL9A3 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 188/603 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs140963282, COSV59650677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COX16 | c.165del p.K55Nfs*2 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs759241200; called by mutect2, varscan2
- COX4I1 | c.322A>G p.M108V | Missense Mutation (SNP) | VAF 40/668 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs768090930; called by muse, mutect2
- CPNE3 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 112/376 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs17853579; called by muse, mutect2, varscan2
- CSF2RB | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 145/439 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs370000670; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 37/124 reads (30%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSMD3 | c.4000G>T p.D1334Y (on ENST00000297405 / NM_001363185.1; = p.D1230Y on NM_052900.3) | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52168572; called by muse, mutect2, varscan2
- CSMD3 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 33/381 reads (9%) | catalogued as rs986319096; called by muse, mutect2
- CST4 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 80/284 reads (28%) | catalogued as rs767756120; called by mutect2, varscan2
- CTNNA2 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 124/387 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.251); catalogued as rs771474697, COSV100781614; called by muse, varscan2
- CTPS1 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 64/295 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV65451973; called by muse, mutect2, varscan2
- CTR9 | c.3239G>A p.R1080Q | Missense Mutation (SNP) | VAF 198/558 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs577509605; called by muse, mutect2, varscan2
- CTTN | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 21/519 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367827428, COSV57235745; called by muse, mutect2
- CUEDC2 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 172/510 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.335); catalogued as rs778209755; called by muse, mutect2, varscan2
- CYP11B2 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 155/426 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as rs745436748, COSV59996500; called by muse, mutect2, varscan2
- CYP1A1 | c.1498C>T p.H500Y | Missense Mutation (SNP) | VAF 124/406 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.15); catalogued as rs1342430592; called by muse, mutect2, varscan2
- CYP1A1 | c.89G>T p.R30I | Missense Mutation (SNP) | VAF 110/359 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV101122322; called by muse, mutect2, varscan2
- CYP26C1 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 182/539 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.149); catalogued as rs1250110324; called by muse, mutect2, varscan2
- CYP2U1 | c.901dup p.I301Nfs*11 | Frame Shift Ins (INS) | VAF 18/113 reads (16%) | catalogued as rs1288449186; called by mutect2, varscan2
- CYYR1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs147481963; called by muse, mutect2, varscan2
- DBI | c.131G>A p.R44Q (on ENST00000355857 / NM_001079862.3; = p.R61Q on NM_020548.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.135); catalogued as rs776979309; called by muse, mutect2, varscan2
- DCAF12L1 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 231/654 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs377390890, COSV64421336; called by muse, mutect2, varscan2
- DCAF4L2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 114/342 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1293407129, COSV100150573, COSV60476409; called by muse, mutect2, varscan2
- DDR2 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 82/236 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.105); catalogued as rs769532262, COSV63369578, COSV63370287; called by muse, mutect2, varscan2
- DDRGK1 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 78/450 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs544094850; called by muse, varscan2
- DDX17 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs1192447183, COSV53254203; called by muse, mutect2
- DDX51 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 142/435 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748206872, COSV57958195; called by muse, mutect2, varscan2
- DENND1C | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 93/385 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.681); catalogued as rs372498127; called by muse, mutect2, varscan2
- DENND4A | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV71266809; called by muse, mutect2, varscan2
- DEPDC1 | c.1064del p.N355Tfs*13 | Frame Shift Del (DEL) | VAF 50/154 reads (32%) | catalogued as rs760464782; called by mutect2, pindel, varscan2
- DGKQ | c.1265C>T p.T422M | Missense Mutation (SNP) | VAF 164/562 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770988014; called by muse, mutect2, varscan2
- DHPS | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 105/335 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV99269527; called by muse, mutect2, varscan2
- DLEU7 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 171/726 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV68546343; called by muse, mutect2, varscan2
- DLG3 | c.2128C>T p.R710W (on ENST00000374360 / NM_021120.4; = p.R405W on NM_020730.3) | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1465036476; called by muse, mutect2, varscan2
- DLGAP3 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 205/664 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs774846562; called by muse, mutect2, varscan2
- DLL1 | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 71/844 reads (8%) | catalogued as COSV64538959; called by muse, mutect2
- DNAH5 | c.877dup p.R293Kfs*6 | Frame Shift Ins (INS) | VAF 98/373 reads (26%) | catalogued as rs781566109; called by mutect2, varscan2
- DNAJC5B | c.14T>C p.I5T | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV52537666; called by muse, mutect2, varscan2
- DND1 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 104/1570 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs750826384, COSV100297875; called by muse, mutect2
- DOCK1 | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.124); catalogued as rs1057180572, COSV54759663; called by muse, varscan2
- DOCK11 | c.4034G>T p.G1345V | Missense Mutation (SNP) | VAF 84/311 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV52237427; called by muse, mutect2, varscan2
- DOCK5 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371773516; called by muse, mutect2, varscan2
- DOP1B | c.6227dup p.R2077Qfs*22 | Frame Shift Ins (INS) | VAF 19/146 reads (13%) | catalogued as rs34641375; called by mutect2, varscan2
- DSC2 | c.2398del p.A800Lfs*56 (on ENST00000280904 / NM_024422.6; = p.A800Lfs*45 on NM_004949.5) | Frame Shift Del (DEL) | VAF 101/420 reads (24%) | catalogued as rs397517399; ClinVar: uncertain significance; called by mutect2, varscan2
- DSC2 | c.1974del p.M658Ifs*24 | Frame Shift Del (DEL) | VAF 28/243 reads (12%) | catalogued as COSV99199878; called by mutect2, pindel, varscan2
- DUSP29 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 117/366 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as rs199896579, COSV58301498; called by muse, varscan2
- DVL1 | c.1774C>T p.R592C (on ENST00000378888 / NM_001330311.2; = p.R567C on NM_004421.3) | Missense Mutation (SNP) | VAF 46/674 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs775705276; called by muse, mutect2
- DYNC1H1 | c.13912C>T p.R4638W | Missense Mutation (SNP) | VAF 107/326 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200224597, COSV64142862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 31/95 reads (33%) | catalogued as rs755197346; called by mutect2, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 34/107 reads (32%) | catalogued as rs772082432; called by mutect2, varscan2
- DYSF | c.3637G>A p.E1213K | Missense Mutation (SNP) | VAF 32/464 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs1260374854; called by muse, mutect2
- DZANK1 | c.1005del p.T336Pfs*55 (on ENST00000262547 / NM_001099407.1; = p.T137Pfs*55 on NM_018152.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 78/396 reads (20%) | catalogued as rs775441744; called by mutect2, pindel, varscan2
- E2F7 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59743756; called by muse, mutect2, varscan2
- EBNA1BP2 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.457); catalogued as rs756079131, COSV52539608; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2191C>T p.R731C | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs889995166, COSV62567748; called by muse, mutect2
- EGFR | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 23/523 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); catalogued as COSV51852585; called by muse, mutect2
- EHBP1L1 | c.2651C>T p.S884L | Missense Mutation (SNP) | VAF 104/449 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs773127792, COSV58571632; called by muse, mutect2, varscan2
- EIF4A1 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 29/234 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV51510374, COSV51511063; called by muse, mutect2, varscan2
- EML2 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 104/317 reads (33%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV55601847; called by muse, mutect2, varscan2
- ENTR1 | c.1010G>A p.R337Q (on ENST00000357365 / NM_001039707.2; = p.R314Q on NM_006643.4) | Missense Mutation (SNP) | VAF 170/252 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs777407699; called by muse, mutect2, varscan2
- EPB41L2 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 76/277 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as rs201590756, COSV61354495; called by muse, mutect2, varscan2
- EPHB1 | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 73/275 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV67659580; called by muse, mutect2, varscan2
- EPHB2 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 58/459 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs372282301; called by muse, varscan2
- EPPK1 | c.2782G>A p.G928S | Missense Mutation (SNP) | VAF 177/575 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs782770978, COSV73261363; called by muse, varscan2
- EQTN | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV66217970; called by muse, mutect2, varscan2
- ERAS | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 184/626 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs782373989, COSV54433255; called by muse, mutect2, varscan2
- ERICH6B | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 31/260 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1472885249; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 19/111 reads (17%) | catalogued as rs753821453; called by mutect2, varscan2
- ESPNL | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 206/634 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1207015036, COSV100547634; called by muse, mutect2, varscan2
- ESR2 | c.1406+4C>T | Splice Region (SNP) | VAF 178/539 reads (33%) | catalogued as rs374485648; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 46/221 reads (21%) | catalogued as rs775950025; called by mutect2, varscan2
- EXOC3L4 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 20/616 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1448487541, COSV66295951; called by muse, mutect2
- EXT2 | c.964C>T p.R322C (on ENST00000343631; = p.R355C on NM_000401.3) | Missense Mutation (SNP) | VAF 32/374 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749297206, COSV59151319; called by muse, mutect2
- EZR | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 182/477 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs780497444, COSV51911079; called by muse, mutect2, varscan2
- FAM110A | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 189/729 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1388858215; called by muse, mutect2, varscan2
- FAM162B | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 39/447 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs764774214, COSV63920216; called by muse, mutect2
- FAM222A | c.961T>C p.Y321H | Missense Mutation (SNP) | VAF 42/806 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.264); catalogued as rs1343313725; called by muse, mutect2
- FAM47C | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 161/582 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.292); catalogued as rs782273885, COSV63726369; called by muse, mutect2, varscan2
- FAM81B | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.396); catalogued as rs766816245, COSV51986543; called by muse, mutect2, varscan2
- FAM83F | c.1161del p.V388Wfs*9 | Frame Shift Del (DEL) | VAF 126/522 reads (24%) | catalogued as rs1569234985; called by mutect2, varscan2
- FARSA | c.1245del p.S416Afs*11 | Frame Shift Del (DEL) | VAF 126/418 reads (30%) | catalogued as COSV100108958; called by mutect2, pindel, varscan2
- FAT1 | c.11846_11847del p.Y3949Cfs*22 | Frame Shift Del (DEL) | VAF 72/386 reads (19%) | catalogued as rs1395974139; called by mutect2, pindel, varscan2
- FAT4 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 143/438 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs774644392, COSV67880788; called by muse, mutect2, varscan2
- FBN2 | c.4868del p.P1623Lfs*26 | Frame Shift Del (DEL) | VAF 71/322 reads (22%) | catalogued as COSV52550220; called by mutect2, pindel, varscan2
- FBN2 | c.3925C>A p.L1309I | Missense Mutation (SNP) | VAF 77/236 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV52550783, COSV99326722; called by muse, mutect2, varscan2
- FBXL13 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs538332474, COSV57534526; called by muse, mutect2, varscan2
- FBXO8 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 79/285 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs529394252, COSV67031050; called by muse, mutect2, varscan2
- FGF5 | c.441dup p.G148Rfs*12 | Frame Shift Ins (INS) | VAF 28/69 reads (41%) | catalogued as rs35667286; called by mutect2, varscan2
- FICD | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 111/436 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs186237475; called by muse, mutect2, varscan2
- FILIP1L | c.2247del p.K749Nfs*2 (on ENST00000354552 / NM_182909.3; = p.K509Nfs*2 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 60/176 reads (34%) | catalogued as COSV58769165; called by mutect2, varscan2
- FMN2 | c.2257G>A p.G753R | Missense Mutation (SNP) | VAF 189/544 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs367554600, COSV100146673; called by muse, mutect2, varscan2
- FN1 | c.6881C>T p.T2294M (on ENST00000359671 / NM_001365524.2; = p.T2263M on NM_002026.4) | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as rs747253191, COSV60548179; called by muse, mutect2, varscan2
- FN1 | c.5695G>A p.A1899T | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.809); catalogued as rs573992192, COSV60547894; called by muse, mutect2, varscan2
- FNDC1 | c.2411C>T p.T804M | Missense Mutation (SNP) | VAF 195/518 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as rs1262947803, COSV51938908; called by muse, varscan2
- FNDC1 | c.3857C>T p.P1286L | Missense Mutation (SNP) | VAF 122/488 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs779321547; called by mutect2, varscan2
- FOXD4 | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 38/734 reads (5%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.001); catalogued as rs147228206; called by muse, mutect2
- FOXD4L5 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 40/1370 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as rs1369867366; called by muse, mutect2
- FOXN2 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 40/158 reads (25%) | catalogued as rs138143881, COSV61319304; called by muse, mutect2, varscan2
- FOXN2 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); catalogued as rs141186693; called by muse, varscan2
- FOXO3 | c.723del p.K242Rfs*117 | Frame Shift Del (DEL) | VAF 99/438 reads (23%) | catalogued as COSV59631234; called by mutect2, pindel, varscan2
- GAB1 | c.50dup p.E18Gfs*34 | Frame Shift Ins (INS) | VAF 111/376 reads (30%) | catalogued as rs755581817; called by mutect2, varscan2
- GABRG1 | c.1205A>G p.Y402C | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.662); catalogued as COSV99778804; called by muse, mutect2, varscan2
- GALNT5 | c.1783G>A p.V595I | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as rs138347479; called by muse, mutect2, varscan2
- GCG | c.322A>G p.S108G | Missense Mutation (SNP) | VAF 63/268 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100972704; called by muse, mutect2, varscan2
- GCGR | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 51/782 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1375779374; called by muse, mutect2
- GDF6 | c.1268C>G p.T423S | Missense Mutation (SNP) | VAF 82/378 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.213); catalogued as rs769886732, COSV54622952; called by muse, mutect2, varscan2
- GFUS | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 136/520 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs201411011; called by muse, varscan2
- GIMAP5 | c.890del p.F297Sfs*30 | Frame Shift Del (DEL) | VAF 118/294 reads (40%) | catalogued as rs774162620, COSV57529761, COSV57529909; called by mutect2, pindel, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs750227570; called by mutect2, varscan2
- GJA8 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 48/662 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781886998; called by muse, mutect2
- GJA8 | c.778A>G p.I260V | Missense Mutation (SNP) | VAF 19/459 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as rs1553242823; called by muse, mutect2
- GJD2 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 180/532 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.377); catalogued as rs780722117, COSV51747534, COSV99290937; called by muse, mutect2
- GLG1 | c.2048C>T p.S683L | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs1288897573; called by muse, mutect2, varscan2
- GLI2 | c.1732G>A p.V578I (on ENST00000361492 / NM_001374353.1; = p.V595I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/662 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.722); catalogued as rs768557650, COSV58043749; called by muse, mutect2
- GLI2 | c.4100G>A p.R1367H (on ENST00000361492 / NM_001374353.1; = p.R1384H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 170/611 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs763852684; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLT6D1 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 59/586 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs183429273; called by muse, mutect2, varscan2
- GNAS | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 155/662 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs570213695, COSV58327309; called by muse, mutect2, varscan2
- GNG3 | c.205_207del p.K69del | In Frame Del (DEL) | VAF 47/260 reads (18%) | catalogued as rs1279576721; called by pindel, varscan2
- GOLGA6L2 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 196/595 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs781719831; called by muse, mutect2, varscan2
- GORASP2 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 148/492 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.009); catalogued as rs778067597, COSV52201913; called by muse, mutect2, varscan2
- GPAA1 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 124/525 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.116); catalogued as rs369331503; called by muse, mutect2, varscan2
- GPC5 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs76285944, COSV100992411; called by muse, mutect2, varscan2
- GPC6 | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV65508777; called by muse, varscan2
- GPC6 | c.299C>A p.S100Y | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as COSV65524075; called by muse, varscan2
- GPR171 | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 48/229 reads (21%) | catalogued as rs770822530; called by muse, mutect2, varscan2
- GPR4 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 144/426 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59917676, COSV59918178; called by muse, mutect2, varscan2
- GPR50 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 25/743 reads (3%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV99505917; called by muse, mutect2
- GPR55 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 108/461 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs569616825; called by muse, mutect2, varscan2
- GPR61 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 188/543 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs949738017, COSV101344415; called by muse, mutect2, varscan2
- GRB14 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs541103423; called by muse, mutect2, varscan2
- GREB1 | c.4901C>A p.P1634Q | Missense Mutation (SNP) | VAF 26/514 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.449); catalogued as COSV52188085; called by muse, mutect2
- GRIA1 | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 94/318 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV99603311; called by muse, mutect2, varscan2
- GRIA3 | c.29G>A p.S10N | Missense Mutation (SNP) | VAF 111/443 reads (25%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV99990941; called by muse, mutect2, varscan2
- GRIN2C | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 55/817 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.037); catalogued as rs192960268; called by muse, mutect2
- GRIN3B | c.2041C>T p.H681Y | Missense Mutation (SNP) | VAF 27/345 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769055248; called by muse, mutect2
- GRM1 | c.3431C>T p.A1144V | Missense Mutation (SNP) | VAF 200/598 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as rs1312527333, COSV51108238; called by muse, mutect2, varscan2
- GSAP | c.2545G>A p.A849T | Missense Mutation (SNP) | VAF 62/270 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755135652, COSV57531357; called by muse, mutect2, varscan2
- GSC2 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 258/713 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50082266; called by muse, mutect2, varscan2
- GTF2IRD1 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 175/660 reads (27%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.461); catalogued as rs1554345370, COSV56084985; called by muse, varscan2
- GTF2IRD1 | c.2698C>T p.R900C (on ENST00000265755 / NM_016328.3; = p.R885C on NM_005685.4) | Missense Mutation (SNP) | VAF 77/519 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs201071085; called by muse, mutect2, varscan2
- GTF3C1 | c.5327G>A p.R1776H | Missense Mutation (SNP) | VAF 36/474 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs928444012, COSV100648891, COSV62244708; called by muse, mutect2
- GTF3C1 | c.2299del p.S767Vfs*7 | Frame Shift Del (DEL) | VAF 62/279 reads (22%) | catalogued as rs1231771183; called by mutect2, pindel, varscan2
- GTPBP1 | c.1817G>C p.G606A | Missense Mutation (SNP) | VAF 129/588 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1379346121, COSV99323624; called by muse, mutect2, varscan2
- GUF1 | c.1927A>G p.K643E | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs545503516, COSV54945907; called by muse, mutect2, varscan2
- H2AC14 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 150/274 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as rs370999596; called by muse, mutect2, varscan2
- H2BC9 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 210/418 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.112); catalogued as rs775679677; called by muse, mutect2, varscan2
- HAUS5 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 110/331 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.319); catalogued as COSV52546804; called by muse, mutect2, varscan2
- HDGFL1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 58/889 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.094); catalogued as rs1413674258, COSV100014505; called by muse, mutect2
- HELZ2 | c.7337C>T p.T2446M (on ENST00000467148 / NM_001037335.2; = p.T1877M on NM_033405.3) | Missense Mutation (SNP) | VAF 188/503 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs544446012; called by muse, varscan2
- HERC1 | c.5948G>A p.R1983H | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs372604267; called by muse, mutect2, varscan2
- HERC2 | c.4519G>A p.A1507T | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); catalogued as rs1184583478, COSV55315251, COSV99870702; called by muse, mutect2, varscan2
- HIPK3 | c.1300dup p.C434Lfs*20 | Frame Shift Ins (INS) | VAF 44/68 reads (65%) | catalogued as rs761758734; called by mutect2, varscan2
- HLA-B | c.19del p.R7Efs*13 | Frame Shift Del (DEL) | VAF 268/554 reads (48%) | catalogued as COSV69520663, COSV69521156; called by mutect2, pindel, varscan2
- HNF1A | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 161/579 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV57468770, COSV99982567; called by muse, mutect2, varscan2
- HNRNPM | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 317/883 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV55313077; called by muse, mutect2, varscan2
- HPS4 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as rs777170572, COSV100404318; called by muse, mutect2, varscan2
- HS6ST2 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 263/761 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs867819607; called by muse, mutect2, varscan2
- HS6ST3 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 343/695 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs139534660, COSV65002195; called by muse, mutect2, varscan2
- HSPG2 | c.1517C>A p.P506H | Missense Mutation (SNP) | VAF 157/482 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65930376; called by muse, mutect2, varscan2
- HTR5A | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 135/650 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as rs780879819, COSV99839524; called by muse, mutect2, varscan2
- ICAM3 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 145/651 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs1217479537; called by muse, mutect2, varscan2
- IFNA1 | c.187del p.Q63Rfs*21 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as rs1425851607; called by mutect2, varscan2
- IGDCC3 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 108/421 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs766994812, COSV60077058; called by muse, mutect2, varscan2
- IGSF9B | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 21/384 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as rs1181741080, COSV58074379; called by muse, mutect2
- IL20RA | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 46/460 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs747471948, COSV57356711; called by muse, mutect2
- IPPK | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 105/553 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs750253794; called by muse, mutect2, varscan2
- IRS2 | c.2495G>A p.R832H | Missense Mutation (SNP) | VAF 171/986 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs780869475; called by muse, mutect2, varscan2
- IRS4 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 24/636 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV64533098; called by muse, mutect2
- IRX6 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 29/393 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV99306478; called by muse, mutect2
- ITGA11 | c.3196G>A p.V1066I | Missense Mutation (SNP) | VAF 85/260 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.036); catalogued as rs199958868; called by muse, mutect2, varscan2
- ITGA2B | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 33/420 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752213788, COSV52234793; called by muse, mutect2
- ITPRID2 | c.2018G>A p.C673Y | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs779639664; called by muse, mutect2, varscan2
- IVD | c.697G>T p.G233C (on ENST00000651168; = p.G230C on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs778857245; called by muse, mutect2, varscan2
- JARID2 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 303/500 reads (61%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.636); catalogued as rs190493478; called by muse, mutect2, varscan2
- JUP | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 108/340 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); catalogued as rs782138974, COSV60278906; called by muse, varscan2
- KAT6A | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs764240239; called by muse, mutect2
- KCNA3 | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 162/507 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63901187; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 77/374 reads (21%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNAB3 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 211/589 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as rs1179077986; called by muse, mutect2, varscan2
- KCND1 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 150/626 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as rs782098842, COSV54416545, COSV99501701; called by muse, mutect2, varscan2
- KCNG2 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 181/787 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs376845551; called by muse, mutect2, varscan2
- KCNH4 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 176/498 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs763598567; called by muse, mutect2, varscan2
- KCNJ12 | c.416A>T p.E139V | Missense Mutation (SNP) | VAF 60/1211 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59164981; called by muse, mutect2
- KCNJ15 | c.1057_1059del p.E353del | In Frame Del (DEL) | VAF 58/198 reads (29%) | catalogued as rs1569023234; called by pindel, varscan2
- KCNK9 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 144/436 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs1340677427, COSV57286527; called by muse, mutect2, varscan2
- KDF1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 186/536 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs143721921; called by muse, mutect2, varscan2
- KDM1A | c.2513G>A p.R838H | Missense Mutation (SNP) | VAF 132/401 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs746357822; called by muse, mutect2, varscan2
- KDM2A | c.3349C>T p.R1117C | Missense Mutation (SNP) | VAF 105/344 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1184539129, COSV58190786; called by muse, mutect2, varscan2
- KHDC3L | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 37/481 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.331); catalogued as COSV64862938; called by muse, mutect2
- KIAA2012 | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 100/294 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs540927894; called by muse, varscan2
- KIF20A | c.2612G>A p.R871Q | Missense Mutation (SNP) | VAF 65/294 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs765098249, COSV101203120; called by muse, mutect2, varscan2
- KIF21B | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 108/456 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs766404118; called by muse, mutect2, varscan2
- KIF3C | c.2369C>T p.A790V | Missense Mutation (SNP) | VAF 88/323 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs150777313; called by muse, mutect2, varscan2
- KIR3DL1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 84/255 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs375468097; called by muse, mutect2
- KIRREL3 | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 119/504 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs745853304, COSV69385033; called by muse, mutect2, varscan2
- KLHL3 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 21/305 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1236385408, COSV59051963; called by muse, mutect2
- KLHL40 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 60/593 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV55134327; called by muse, mutect2, varscan2
- KMT2C | c.12194C>T p.A4065V | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs141966811, COSV51437723; called by muse, mutect2, varscan2
- KMT2D | c.6794del p.G2265Efs*21 | Frame Shift Del (DEL) | VAF 230/696 reads (33%) | catalogued as CD146890; called by mutect2, pindel, varscan2
- KNG1 | c.675T>C p.D225= | Splice Region (SNP) | VAF 33/101 reads (33%) | catalogued as rs781186664; called by muse, mutect2, varscan2
- KNTC1 | c.4229G>A p.R1410H | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1366701984, COSV61079421; called by muse, mutect2
- KRBA1 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 51/994 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as rs888089241; called by muse, mutect2
- KRT6C | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 89/376 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as rs761980436, COSV52877654; called by muse, mutect2, varscan2
- LAMB3 | c.2569G>A p.E857K | Missense Mutation (SNP) | VAF 97/341 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774367298; called by muse, mutect2, varscan2
- LAMB3 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 98/404 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.671); catalogued as rs113063967, COSV61916743; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 47/150 reads (31%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LDB1 | c.887G>A p.R296Q (on ENST00000425280 / NM_001321612.2; = p.R260Q on NM_003893.5) | Missense Mutation (SNP) | VAF 35/503 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as COSV63289931; called by muse, mutect2
- LEFTY2 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 146/562 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs755576793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LGALS12 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 69/304 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1159880842; called by muse, mutect2, varscan2
- LIMK2 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 42/395 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.065); catalogued as rs752914428, COSV59182330; called by muse, mutect2
- LIN7A | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 116/436 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.486); catalogued as COSV54023917; called by muse, varscan2
- LINGO1 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 22/391 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as rs368298715; called by muse, mutect2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 61/178 reads (34%) | catalogued as rs780042765; called by mutect2, varscan2
- LMBR1 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 26/138 reads (19%) | catalogued as rs377662885; called by muse, mutect2, varscan2
- LPCAT4 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 96/422 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs575211382, COSV59217216; called by muse, mutect2, varscan2
- LRBA | c.4595del p.L1532* | Frame Shift Del (DEL) | VAF 29/111 reads (26%) | catalogued as COSV63963298; called by mutect2, pindel, varscan2
- LRFN1 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 175/535 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs755458726, COSV50470740; called by muse, mutect2, varscan2
- LRFN2 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 42/405 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as rs1338608982, COSV100599388, COSV57824249; called by muse, mutect2, varscan2
- LRP1 | c.11278C>T p.R3760C | Missense Mutation (SNP) | VAF 238/597 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs548508591; called by muse, mutect2, varscan2
- LRRC4B | c.1490C>T p.T497M | Missense Mutation (SNP) | VAF 216/683 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.154); catalogued as rs763207062, COSV65349197; called by muse, mutect2, varscan2
- LSS | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 132/433 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs745641322, COSV62701472; called by muse, mutect2, varscan2
- MAFA | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 113/315 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs774483749; called by muse, mutect2, varscan2
- MAN2A1 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs757758693, COSV54846497; called by muse, mutect2
- MAN2A2 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 174/639 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.107); catalogued as rs370992775; called by muse, mutect2, varscan2
- MAP2K7 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 83/325 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1441304667, COSV67608310, COSV67609148; called by muse, varscan2
- MAP3K21 | c.2869C>T p.P957S | Missense Mutation (SNP) | VAF 143/518 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as rs200413184; called by muse, mutect2, varscan2
- MAP6 | c.1753G>T p.G585C | Missense Mutation (SNP) | VAF 120/552 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.319); catalogued as rs545778; called by muse, mutect2, varscan2
- MAPK13 | c.120C>T p.C40= | Splice Region (SNP) | VAF 27/218 reads (12%) | catalogued as rs766204139; called by muse, mutect2, varscan2
- MAPK3 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 41/496 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1291454132; called by muse, mutect2
- MAPK8IP3 | c.2378C>T p.P793L | Missense Mutation (SNP) | VAF 200/553 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759234530; called by muse, mutect2, varscan2
- MAST1 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 103/306 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV52241333; called by muse, mutect2, varscan2
- MAST4 | c.6493del p.A2165Pfs*118 (on ENST00000403625 / NM_001164664.2; = p.A1976Pfs*118 on NM_015183.3) | Frame Shift Del (DEL) | VAF 186/660 reads (28%) | catalogued as COSV99844049; called by mutect2, pindel, varscan2
- MCF2 | c.2092G>A p.G698S | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs763401630, COSV58480281; called by muse, mutect2, varscan2
- MCM9 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 71/264 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs1257707971, COSV100309587; called by muse, mutect2, varscan2
- MCRS1 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 42/651 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1420075161, COSV100657398, COSV59458754; called by muse, mutect2
- MED15 | c.1975G>A p.V659M (on ENST00000263205 / NM_001003891.3; = p.V619M on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/500 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.121); catalogued as rs780911694, COSV99487720; called by muse, mutect2
- MEDAG | c.375del p.D126Tfs*12 | Frame Shift Del (DEL) | VAF 65/155 reads (42%) | catalogued as rs1418142218, COSV66849992; called by mutect2, pindel, varscan2
- MEGF10 | c.1514del p.G505Efs*32 | Frame Shift Del (DEL) | VAF 136/432 reads (31%) | catalogued as COSV57257411, COSV99174837; called by mutect2, varscan2
- MEIKIN | c.763dup p.T255Nfs*13 | Frame Shift Ins (INS) | VAF 34/112 reads (30%) | catalogued as rs1194023774; called by mutect2, pindel, varscan2
- MEN1 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 17/411 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1208267598, COSV56340140; ClinVar: uncertain significance; called by muse, mutect2
- MFAP1 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 93/257 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773363920; called by muse, mutect2, varscan2
- MFSD14A | c.806dup p.L269Ffs*43 | Frame Shift Ins (INS) | VAF 30/116 reads (26%) | catalogued as rs780635289; called by mutect2, varscan2
- MFSD6 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 79/283 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.63); catalogued as rs368011115; called by muse, mutect2, varscan2
- MICAL3 | c.4823C>T p.A1608V | Missense Mutation (SNP) | VAF 62/717 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs532711017; called by muse, mutect2
- MIEF2 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 46/748 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.253); catalogued as rs1170073251, COSV100493393, COSV100493444; called by muse, mutect2
- MIOX | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 160/450 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs145084575; called by muse, mutect2, varscan2
- MLANA | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 94/443 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1174172878, COSV67366719; called by muse, mutect2, varscan2
- MMRN2 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 50/592 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1457155695, COSV100922533; called by muse, mutect2
- MN1 | c.3716C>T p.A1239V | Missense Mutation (SNP) | VAF 164/470 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs1216829399; called by muse, mutect2, varscan2
- MOCS1 | c.1894dup p.D632Gfs*43 | Frame Shift Ins (INS) | VAF 153/379 reads (40%) | catalogued as rs747994218; called by pindel, varscan2
- MPO | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 42/523 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs1326229205, COSV56566645; called by muse, mutect2
- MPP2 | c.298C>T p.R100W (on ENST00000461854 / NM_001278372.2; = p.R76W on NM_005374.5) | Missense Mutation (SNP) | VAF 148/524 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs562847000, COSV99290661; called by muse, mutect2, varscan2
- MPPED1 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 161/446 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs759429599, COSV61987403; called by muse, mutect2, varscan2
- MROH2B | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.434); catalogued as rs372907780; called by muse, mutect2, varscan2
- MRTFB | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 110/327 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100371750; called by muse, mutect2, varscan2
- MSGN1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 148/544 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV55263497; called by muse, mutect2, varscan2
- MTMR6 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1328876968, COSV67809010; called by muse, mutect2, varscan2
- MTSS2 | c.1128G>A p.S376= | Splice Region (SNP) | VAF 109/406 reads (27%) | catalogued as rs144454833; called by muse, mutect2, varscan2
- MUC16 | c.18182C>A p.P6061H | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.353); catalogued as COSV101199434; called by muse, mutect2
- MUC17 | c.7223C>T p.P2408L | Missense Mutation (SNP) | VAF 152/728 reads (21%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.913); catalogued as rs140211048; called by muse, mutect2, varscan2
- MVK | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 143/543 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57333080; called by muse, mutect2, varscan2
- MXRA8 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 211/674 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557682497; called by muse, mutect2, varscan2
- MYH14 | c.3581C>T p.T1194M | Missense Mutation (SNP) | VAF 115/412 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs200988515; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH2 | c.5405G>A p.R1802H | Missense Mutation (SNP) | VAF 160/518 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs777282924, COSV55447559, COSV55449799; called by muse, mutect2, varscan2
- MYO15B | c.7517G>A p.R2506H | Missense Mutation (SNP) | VAF 136/427 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs933112543; called by muse, mutect2, varscan2
- MYOM3 | c.3583C>T p.R1195* | Nonsense Mutation (SNP) | VAF 31/418 reads (7%) | catalogued as rs1298452784, COSV58402181; called by muse, mutect2
- MYOM3 | c.1994C>T p.T665M | Missense Mutation (SNP) | VAF 88/304 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs148441250, COSV58394688; called by muse, mutect2, varscan2
- MYT1L | c.3104C>T p.A1035V | Missense Mutation (SNP) | VAF 30/450 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.234); catalogued as COSV67702286; called by muse, mutect2
- MYT1L | c.3020C>T p.T1007M | Missense Mutation (SNP) | VAF 145/453 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1278344930, COSV101217070, COSV67702885; called by muse, mutect2, varscan2
- NAP1L3 | c.286T>G p.F96V | Missense Mutation (SNP) | VAF 112/428 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV59077456; called by muse, varscan2
- NASP | c.478del p.T160Qfs*29 | Frame Shift Del (DEL) | VAF 59/205 reads (29%) | catalogued as COSV100601638; called by mutect2, pindel, varscan2
- NBEAL1 | c.4228C>T p.H1410Y | Missense Mutation (SNP) | VAF 75/187 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs1221009867; called by muse, mutect2, varscan2
- NCKAP5 | c.5267C>G p.S1756* | Nonsense Mutation (SNP) | VAF 110/556 reads (20%) | catalogued as COSV58428369; called by muse, mutect2, varscan2
- NCOA3 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs267605972; called by muse, mutect2, varscan2
- NCOA5 | c.1118G>T p.R373L | Missense Mutation (SNP) | VAF 98/344 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99275207; called by muse, mutect2, varscan2
- NEFM | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 95/294 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55330511; called by muse, mutect2, varscan2
- NGFR | c.817A>G p.K273E | Missense Mutation (SNP) | VAF 81/295 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs767218972; called by muse, mutect2, varscan2
- NINL | c.2783C>T p.A928V | Missense Mutation (SNP) | VAF 207/608 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs745573045, COSV53998029; called by muse, mutect2, varscan2
- NLRP3 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 176/555 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as rs762512734, COSV60229623; called by muse, mutect2, varscan2
- NMUR1 | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 68/784 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.044); catalogued as rs745366125, COSV59404516; called by muse, mutect2
- NOCT | c.925C>A p.Q309K | Missense Mutation (SNP) | VAF 38/481 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs368722959; called by muse, mutect2
- NPHP4 | c.2486G>A p.G829D | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778107434; called by muse, mutect2, varscan2
- NPTX2 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 231/453 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369863365; called by muse, mutect2, varscan2
- NR0B1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 176/633 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.628); catalogued as rs104894888, CM940013; called by muse, mutect2, varscan2
- NR2F1 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 154/527 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as COSV100504714; called by muse, mutect2, varscan2
- NR2F1 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 185/551 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59067492; called by muse, mutect2, varscan2
- NRBP1 | c.591dup p.I198Hfs*9 | Frame Shift Ins (INS) | VAF 117/330 reads (35%) | catalogued as rs763892200; called by mutect2, varscan2
- NRIP1 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.573); catalogued as rs755926461, COSV59658452; called by muse, mutect2, varscan2
- NTN1 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 38/475 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs1420549242; called by muse, mutect2
- NTNG1 | c.451A>G p.T151A | Missense Mutation (SNP) | VAF 20/311 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99639400; called by muse, mutect2
- NUP210 | c.403dup p.L135Pfs*116 | Frame Shift Ins (INS) | VAF 122/402 reads (30%) | catalogued as rs762804106; called by mutect2, pindel, varscan2
- NXPE4 | c.1283dup p.N428Kfs*18 (on ENST00000375478 / NM_001077639.2; = p.N144Kfs*18 on NM_017678.3) | Frame Shift Ins (INS) | VAF 129/209 reads (62%) | catalogued as rs1475536101; called by mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 168/650 reads (26%) | catalogued as rs762005098; called by mutect2, varscan2
- OBSL1 | c.2174C>T p.S725L | Missense Mutation (SNP) | VAF 117/391 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs757084713; called by muse, mutect2, varscan2
- OCA2 | c.2381C>T p.A794V | Missense Mutation (SNP) | VAF 92/376 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as COSV62352688; called by muse, mutect2
- OCA2 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 176/549 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as rs201904219, COSV62357834; called by muse, mutect2, varscan2
- OLFML3 | c.795dup p.Y266Lfs*14 | Frame Shift Ins (INS) | VAF 132/394 reads (34%) | catalogued as rs753594963; called by mutect2, varscan2
- ONECUT2 | c.1057del p.Q353Rfs*123 | Frame Shift Del (DEL) | VAF 189/650 reads (29%) | catalogued as COSV101529825; called by mutect2, pindel, varscan2
- ONECUT3 | c.29del p.G10Afs*14 | Frame Shift Del (DEL) | VAF 102/357 reads (29%) | catalogued as rs1335499382; called by mutect2, pindel, varscan2
- OPLAH | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 139/531 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.394); catalogued as rs1468778573; called by muse, mutect2, varscan2
- OR13G1 | c.424C>T p.L142F | Missense Mutation (SNP) | VAF 96/322 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs373225231; called by muse, mutect2, varscan2
- OR14J1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1022608299, COSV65845778; called by muse, mutect2
- OR1Q1 | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 111/509 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52919073; called by muse, mutect2, varscan2
- OR2A4 | c.532del p.C178Vfs*37 | Frame Shift Del (DEL) | VAF 53/443 reads (12%) | catalogued as rs763408926; called by mutect2, pindel, varscan2
- OR2L2 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 55/220 reads (25%) | catalogued as rs746095999, COSV63549022, COSV63556852; called by mutect2, pindel, varscan2
- OR4A5 | c.312C>A p.F104L | Missense Mutation (SNP) | VAF 115/319 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs866826742, COSV60521518; called by muse, mutect2, varscan2
- OR4X1 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 265/394 reads (67%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.791); catalogued as rs568260658, COSV100186677, COSV60723069; called by muse, mutect2, varscan2
- OR5W2 | c.72A>T p.K24N | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV60615220, COSV60618884; called by muse, mutect2, varscan2
- OR6K6 | c.935del p.F312Sfs*8 (on ENST00000368144; = p.F288Sfs*8 on NM_001005184.1) | Frame Shift Del (DEL) | VAF 53/201 reads (26%) | catalogued as COSV63743557; called by mutect2, pindel, varscan2
- P2RY6 | c.975G>T p.R325S | Missense Mutation (SNP) | VAF 164/245 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs1472061790; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.691G>A p.V231I (on ENST00000259318 / NM_001136562.3; = p.V462I on NM_007203.5) | Missense Mutation (SNP) | VAF 352/501 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs139564817, COSV52173723; called by muse, mutect2, varscan2
- PANK4 | c.667T>G p.W223G | Missense Mutation (SNP) | VAF 20/632 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101022328; called by muse, mutect2
- PAOX | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 38/620 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.245); catalogued as rs890302796, COSV53374410, COSV99530028; called by muse, mutect2
- PAQR9 | c.584del p.R195Pfs*98 | Frame Shift Del (DEL) | VAF 122/580 reads (21%) | catalogued as COSV61418720; called by pindel, varscan2
- PARD3B | c.3110G>A p.R1037Q (on ENST00000406610 / NM_001302769.2; = p.R968Q on NM_057177.7) | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs772027661, COSV62526773; called by muse, mutect2, varscan2
- PARP1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 118/339 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs757712451, COSV64688042; called by muse, mutect2, varscan2
- PASK | c.1864C>T p.R622* | Nonsense Mutation (SNP) | VAF 179/611 reads (29%) | catalogued as rs773934506; called by muse, mutect2, varscan2
- PAX7 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 201/626 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs769536224, COSV100946625; called by muse, mutect2, varscan2
- PAXBP1 | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 31/122 reads (25%) | catalogued as COSV51607465; called by muse, mutect2, varscan2
- PBRM1 | c.2627G>A p.R876H | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56269665, COSV56274390; called by muse, mutect2, varscan2
- PBX1 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 78/251 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as COSV63343447; called by muse, mutect2, varscan2
- PCDH17 | c.3180A>C p.K1060N | Missense Mutation (SNP) | VAF 113/663 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.436); catalogued as COSV64971554, COSV64973819, COSV64979680; called by muse, mutect2, varscan2
- PCDHA1 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 275/807 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as rs782599305, COSV65373425; called by muse, mutect2, varscan2
- PCDHB11 | c.2125G>A p.V709M | Missense Mutation (SNP) | VAF 251/836 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.379); catalogued as rs781839995, COSV61313848, COSV61313955; called by muse, mutect2, varscan2
- PCDHB16 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 222/669 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.65); catalogued as rs368338519; called by muse, mutect2, varscan2
- PCDHB6 | c.2164C>T p.R722C | Missense Mutation (SNP) | VAF 26/832 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1440784518, COSV50702048; called by muse, mutect2
- PCDHGA6 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 88/461 reads (19%) | catalogued as COSV54007546; called by mutect2, varscan2
- PCDHGA6 | c.1639T>C p.S547P | Missense Mutation (SNP) | VAF 219/644 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.962); catalogued as rs1422655230; called by muse, mutect2, varscan2
- PCLO | c.15188del p.K5063Rfs*2 | Frame Shift Del (DEL) | VAF 26/158 reads (16%) | catalogued as rs1405726136; called by mutect2, pindel, varscan2
- PCLO | c.7172G>A p.R2391H | Missense Mutation (SNP) | VAF 123/261 reads (47%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs749073112, COSV104415213; called by muse, mutect2, varscan2
- PCNX1 | c.4834C>T p.R1612W | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53098102; called by muse, mutect2, varscan2
- PDCD11 | c.4707G>A p.T1569= | Splice Region (SNP) | VAF 89/245 reads (36%) | catalogued as rs760657326, COSV53297689; called by muse, mutect2, varscan2
- PDE7A | c.1179del p.K393Nfs*6 (on ENST00000401827 / NM_001242318.3; = p.K367Nfs*6 on NM_002603.4) | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | catalogued as rs776556726; called by mutect2, varscan2
- PDE8B | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 103/297 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.934); catalogued as rs747059922, COSV53732486, COSV53733876; called by muse, mutect2, varscan2
- PDZRN3 | c.2325del p.D776Tfs*4 | Frame Shift Del (DEL) | VAF 60/506 reads (12%) | catalogued as COSV55192914; called by pindel, varscan2
- PDZRN3 | c.2017G>A p.A673T | Missense Mutation (SNP) | VAF 161/505 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs370987104; called by muse, mutect2, varscan2
- PGK1 | c.173T>C p.V58A | Missense Mutation (SNP) | VAF 132/430 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1410483316; called by muse, mutect2, varscan2
- PHACTR3 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 78/354 reads (22%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.018); catalogued as rs957244465; called by muse, mutect2, varscan2
- PHKG1 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 190/388 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs767151786, COSV51916388, COSV99304994; called by muse, varscan2
- PHYHIPL | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs1430293756, COSV65848263; called by muse, mutect2, varscan2
- PIDD1 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 423/629 reads (67%) | catalogued as rs142408616; called by muse, varscan2
- PIK3C2B | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 164/494 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs182252171, COSV65803884; called by muse, mutect2, varscan2
- PIP5K1C | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 75/329 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs752717133, COSV58951018; called by muse, mutect2, varscan2
- PIWIL4 | c.1858G>A p.V620I | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.383); catalogued as COSV100133270; called by muse, mutect2, varscan2
- PKD1 | c.6098C>T p.A2033V | Missense Mutation (SNP) | VAF 164/635 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs557932393; called by muse, mutect2, varscan2
- PKHD1 | c.5402G>A p.G1801D | Missense Mutation (SNP) | VAF 53/274 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1479308455; called by muse, mutect2, varscan2
- PKN3 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 48/715 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775416496; called by muse, mutect2
- PLD1 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as rs368807491, COSV104415999; called by muse, mutect2, varscan2
- PLEKHA7 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 58/760 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs866233465, COSV63047063; called by muse, mutect2
- PLIN5 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 198/622 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs757461297; called by muse, varscan2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 52/178 reads (29%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POLG | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 58/431 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.505); catalogued as rs1394160595; called by muse, mutect2, varscan2
- POTEF | c.2137G>A p.G713S | Missense Mutation (SNP) | VAF 136/798 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as rs1255649346; called by muse, varscan2
- POTEI | c.2648G>A p.R883Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs1194348367; called by mutect2, varscan2
- POTEJ | c.2537G>A p.R846Q | Missense Mutation (SNP) | VAF 59/521 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.974); catalogued as rs777778167; called by muse, mutect2, varscan2
- PPFIA2 | c.2764C>T p.R922* | Nonsense Mutation (SNP) | VAF 93/315 reads (30%) | catalogued as COSV100335777; called by muse, mutect2, varscan2
- PPL | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 107/384 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs961039974; called by muse, mutect2, varscan2
- PPM1D | c.1535del p.N512Ifs*2 | Frame Shift Del (DEL) | VAF 58/257 reads (23%) | catalogued as rs763475304; called by mutect2, pindel, varscan2
- PPP2R3B | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 105/384 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.383); catalogued as rs760244257, COSV66813342; called by muse, mutect2, varscan2
- PPP6R1 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 91/344 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs766251322; called by muse, mutect2, varscan2
- PPP6R2 | c.2774C>T p.A925V (on ENST00000216061 / NM_001365836.1; = p.A891V on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 228/697 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs765174979, COSV53299985; called by muse, mutect2, varscan2
- PPRC1 | c.4549C>T p.R1517W | Missense Mutation (SNP) | VAF 98/318 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776378929, COSV53385256; called by muse, mutect2, varscan2
- PRAMEF20 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 18/445 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.048); catalogued as rs1200392559; called by muse, mutect2
- PRAMEF4 | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 141/534 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1178572416; called by muse, mutect2
- PRKAB1 | c.80del p.G27Afs*11 | Frame Shift Del (DEL) | VAF 144/602 reads (24%) | catalogued as COSV57555398; called by mutect2, varscan2
- PRR14L | c.5607A>G p.I1869M | Missense Mutation (SNP) | VAF 110/379 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57884106; called by muse, mutect2, varscan2
- PRR23A | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 125/500 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as COSV101270373; called by muse, mutect2, varscan2
- PRR23B | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 42/596 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.193); catalogued as COSV61495037; called by muse, mutect2
- PRR32 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 202/592 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV64420948; called by muse, mutect2, varscan2
- PRR35 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 230/721 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766107824; called by muse, mutect2
- PRSS1 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 66/906 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as rs201775810, COSV61191219; called by muse, mutect2
- PRUNE2 | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 30/528 reads (6%) | catalogued as rs1324608847, COSV65028146; called by muse, mutect2
- PRX | c.4172G>A p.R1391Q | Missense Mutation (SNP) | VAF 228/626 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs917161355, COSV52519697; called by muse, varscan2
- PRX | c.2107G>A p.D703N | Missense Mutation (SNP) | VAF 130/531 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.312); catalogued as rs756173103; called by muse, mutect2, varscan2
- PSEN1 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 84/266 reads (32%) | catalogued as COSV56193797; called by muse, mutect2, varscan2
- PSMA7 | c.522_524del p.K174del | In Frame Del (DEL) | VAF 61/266 reads (23%) | catalogued as rs1443449233; called by pindel, varscan2
- PSMB8 | c.599C>T p.T200M (on ENST00000374882 / NM_148919.4; = p.T196M on NM_004159.5) | Missense Mutation (SNP) | VAF 44/594 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs554683045; called by muse, mutect2
- PTCD1 | c.1690G>A p.G564R | Missense Mutation (SNP) | VAF 125/548 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs769687022; called by muse, varscan2
- PTCH2 | c.3505dup p.L1169Pfs*11 | Frame Shift Ins (INS) | VAF 128/562 reads (23%) | catalogued as rs763413121; called by mutect2, varscan2
- PTCHD4 | c.2465G>A p.R822H | Missense Mutation (SNP) | VAF 152/258 reads (59%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs769671626, COSV100261787; called by muse, mutect2, varscan2
- PTF1A | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 114/346 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1465898216, COSV64735241; called by muse, varscan2
- PTGFRN | c.1745G>A p.R582H | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs376621300; called by muse, mutect2, varscan2
- PTPRS | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 228/662 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs919253826, COSV53619310; called by muse, mutect2, varscan2
- PTPRS | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 36/534 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53644396; called by muse, mutect2
- PUS7 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 51/348 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs144060501; called by muse, mutect2, varscan2
- PXDN | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 85/274 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1347326598; called by muse, mutect2, varscan2
- PYGO2 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 167/650 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63757338; called by muse, mutect2, varscan2
- RAB20 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 26/780 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs1241794886, COSV57440342; called by muse, mutect2
- RBM15B | c.2529del p.S844Pfs*27 | Frame Shift Del (DEL) | VAF 210/657 reads (32%) | catalogued as rs781825075; called by mutect2, pindel, varscan2
- RBM25 | c.1612A>G p.R538G | Missense Mutation (SNP) | VAF 107/283 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV56202324; called by muse, mutect2, varscan2
- RBM42 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 219/624 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as rs201842352; called by muse, varscan2
- RBM43 | c.406del p.I136Sfs*4 | Frame Shift Del (DEL) | VAF 50/98 reads (51%) | catalogued as rs142934811, CD1212851; called by mutect2, varscan2
- RCC2 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.174); catalogued as rs758217920; called by muse, varscan2
- RELA | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 143/543 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV58015334; called by muse, mutect2, varscan2
- RET | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 22/412 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.461); catalogued as rs754859905, COSV60695046; called by muse, mutect2
- RHOBTB1 | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 108/310 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.368); catalogued as rs138580713, COSV61957775; called by muse, mutect2, varscan2
- RHOG | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 348/550 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV53464891, COSV99544135; called by muse, mutect2, varscan2
- RIC8A | c.1120C>T p.R374W (on ENST00000526104 / NM_001286134.1; = p.R380W on NM_021932.5) | Missense Mutation (SNP) | VAF 56/656 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775675601; called by muse, mutect2
- RIN1 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 40/861 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as rs748809722; called by muse, mutect2
- RNASEL | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 143/424 reads (34%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.763); catalogued as rs762520521, COSV62376819; called by muse, mutect2, varscan2
- RNF43 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 18/398 reads (5%) | catalogued as COSV68457287, COSV68458942; called by muse, mutect2
- RNMT | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs576605287, COSV51084075; called by muse, mutect2, varscan2
- RNPEPL1 | c.1864C>T p.R622W | Missense Mutation (SNP) | VAF 106/314 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs193086300; called by muse, mutect2, varscan2
- RPF1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772841146, COSV65705876; called by muse, varscan2
- RPL22L1 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as rs755978751, COSV55556992; called by muse, mutect2, varscan2
- RPN1 | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1359838705, COSV56189160; called by muse, mutect2, varscan2
- RPUSD1 | c.774del p.D259Tfs*71 | Frame Shift Del (DEL) | VAF 200/555 reads (36%) | catalogued as rs1567375215; called by mutect2, varscan2
- RSPH10B2 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 81/373 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.548); catalogued as rs775750499; called by muse, mutect2, varscan2
- RUVBL1 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs141069437; called by muse, mutect2, varscan2
- RXRA | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 41/676 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV62683568; called by muse, mutect2
- RYR1 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs193922759, CM064222, COSV62102179; ClinVar: not provided; called by muse, mutect2, varscan2
- RYR1 | c.7697C>T p.A2566V | Missense Mutation (SNP) | VAF 64/742 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as rs1285547623, COSV62089550; called by muse, mutect2
- S100A3 | c.294del p.C99Afs*54 | Frame Shift Del (DEL) | VAF 104/350 reads (30%) | catalogued as rs1279717323; called by mutect2, pindel, varscan2
- SACS | c.5875A>T p.I1959F | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV101207133; called by muse, mutect2, varscan2
- SAFB | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 40/570 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201408665; called by muse, mutect2
- SARDH | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 44/667 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1366811300, COSV53832611, COSV53833571; called by muse, mutect2
- SASH1 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as rs768187643; called by muse, mutect2, varscan2
- SASH1 | c.3047C>T p.A1016V | Missense Mutation (SNP) | VAF 195/664 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs367842173; called by muse, mutect2, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 58/186 reads (31%) | catalogued as COSV54589079; called by mutect2, varscan2
- SCN4B | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 230/340 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs755758222; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC61A1 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 95/388 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs750396475, COSV54577460, COSV54578577; called by muse, mutect2, varscan2
- SEMA5B | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 102/415 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as rs1381311028; called by muse, mutect2, varscan2
- SFXN4 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 79/318 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751311051, COSV57460501; called by muse, mutect2, varscan2
- SGSM3 | c.1963C>T p.R655C | Missense Mutation (SNP) | VAF 38/478 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773271072, COSV99960521; called by muse, mutect2
- SHANK1 | c.4888G>A p.E1630K | Missense Mutation (SNP) | VAF 188/583 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.176); catalogued as COSV53253144; called by muse, mutect2, varscan2
- SHANK3 | c.2785G>A p.A929T | Missense Mutation (SNP) | VAF 144/433 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.112); catalogued as rs1356871680; called by muse, mutect2, varscan2
- SHH | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 162/985 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as CM095874; called by muse, mutect2, varscan2
- SIGLEC11 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1253286759; called by muse, mutect2, varscan2
- SKOR1 | c.1700C>T p.T567M | Missense Mutation (SNP) | VAF 191/596 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1283803696; called by muse, mutect2, varscan2
- SLAMF7 | c.375C>T p.Y125= | Splice Region (SNP) | VAF 77/223 reads (35%) | catalogued as rs778677363, COSV63564146; called by muse, mutect2, varscan2
- SLC10A4 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 172/618 reads (28%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.007); catalogued as rs1327126233; called by muse, mutect2, varscan2
- SLC23A1 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 36/460 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs774710051; called by muse, mutect2
- SLC26A11 | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 30/436 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.159); catalogued as rs781211086, COSV58339420; called by muse, mutect2
- SLC2A5 | c.875G>A p.G292D | Missense Mutation (SNP) | VAF 102/352 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1394654972; called by muse, mutect2, varscan2
- SLC30A1 | c.207_209del p.K69del | In Frame Del (DEL) | VAF 183/590 reads (31%) | catalogued as rs769620820; called by pindel, varscan2
- SLC35F1 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 81/222 reads (36%) | catalogued as rs758791782, COSV64499299; called by muse, mutect2, varscan2
- SLC35F6 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 32/498 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs760556570, COSV100733597; called by muse, mutect2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 88/142 reads (62%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC3A1 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 111/467 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765828196, CM951165, COSV99037704; called by muse, mutect2, varscan2
- SLC4A10 | c.1577C>T p.T526M (on ENST00000446997 / NM_001354461.2; = p.T496M on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1313617772, COSV55767205; called by muse, mutect2, varscan2
- SLC6A19 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 139/553 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as rs377603594, COSV58673156, COSV58675005; called by muse, mutect2, varscan2
- SLC6A3 | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 32/571 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs753749540, COSV54366972; called by muse, mutect2
- SLC8B1 | c.1342G>T p.G448C | Missense Mutation (SNP) | VAF 172/551 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242132170; called by muse, mutect2, varscan2
- SLC9A2 | c.1165T>C p.W389R | Missense Mutation (SNP) | VAF 39/368 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52129591; called by muse, mutect2, varscan2
- SLFN5 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1171032131, COSV55480875; called by muse, mutect2, varscan2
- SLIT2 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs780111778, COSV56564001; called by muse, mutect2
- SLITRK2 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 154/422 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.861); catalogued as rs1556943721, COSV59424688; called by muse, mutect2, varscan2
- SLITRK2 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 90/331 reads (27%) | catalogued as COSV100158178; called by muse, mutect2, varscan2
- SLK | c.10_12del p.F4del | In Frame Del (DEL) | VAF 47/147 reads (32%) | catalogued as rs779771559; called by pindel, varscan2
- SMC1B | c.484G>T p.G162* | Nonsense Mutation (SNP) | VAF 47/117 reads (40%) | catalogued as rs80044061; called by muse, mutect2, varscan2
- SMG1 | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs1473768883; called by muse, mutect2, varscan2
- SMG7 | c.2911G>C p.A971P | Missense Mutation (SNP) | VAF 26/345 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV61634612; called by muse, mutect2
- SMTN | c.2017G>A p.V673I | Missense Mutation (SNP) | VAF 36/539 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs771689259, COSV60784003; called by muse, mutect2
- SNAPC2 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 121/367 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs748259097; called by muse, mutect2, varscan2
- SOGA1 | c.3239G>A p.R1080H | Missense Mutation (SNP) | VAF 160/509 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs866971190, COSV52929487, COSV52932913; called by muse, varscan2
- SORCS3 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 226/680 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1360566197; called by muse, mutect2, varscan2
- SOX21 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 326/721 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65375250; called by muse, mutect2, varscan2
- SPAG6 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs918860729, COSV57620478; called by muse, mutect2, varscan2
- SPECC1 | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs765903879, COSV54954710, COSV54955461; called by muse, mutect2, varscan2
- SPEG | c.2140G>A p.A714T | Missense Mutation (SNP) | VAF 94/389 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs767867804, COSV100403249, COSV100404057, COSV56676473; called by muse, mutect2, varscan2
- SPEG | c.2744G>A p.R915H | Missense Mutation (SNP) | VAF 172/574 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.061); catalogued as rs778684137, COSV56665740; called by muse, mutect2, varscan2
- SPINK5 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs774354593, COSV56253349; called by muse, mutect2, varscan2
- SPOCK3 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs560446612, COSV100692812; called by muse, mutect2, varscan2
- SPTAN1 | c.3161G>A p.R1054H | Missense Mutation (SNP) | VAF 32/489 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs561564501, COSV63986436; ClinVar: uncertain significance; called by muse, mutect2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 53/240 reads (22%) | catalogued as rs748467821; called by mutect2, varscan2
- SREBF1 | c.2779C>T p.R927W | Missense Mutation (SNP) | VAF 165/501 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs779739510; called by muse, mutect2, varscan2
- SRGAP3 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 107/350 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64530776; called by muse, mutect2, varscan2
- SRRM4 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 63/175 reads (36%) | catalogued as COSV57408995; called by muse, mutect2, varscan2
- SSX2IP | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as rs139834938, COSV60553474; called by muse, mutect2, varscan2
- STAM | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs782614712; called by muse, mutect2, varscan2
- STAT1 | c.1946G>A p.R649H | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); catalogued as rs1245176183, COSV63116880; called by muse, mutect2, varscan2
- STIL | c.3756del p.P1253Lfs*10 | Frame Shift Del (DEL) | VAF 22/246 reads (9%) | catalogued as rs995755122; called by mutect2, pindel
- SUCNR1 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 103/362 reads (28%) | SIFT tolerated (0.98); PolyPhen benign (0.03); catalogued as rs778527962, COSV62911883; called by muse, mutect2, varscan2
- SULF2 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 95/329 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.086); catalogued as rs763698817, COSV63418452; called by muse, mutect2, varscan2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | catalogued as rs747003550; called by mutect2, varscan2
- SYCP1 | c.1884del p.G629Vfs*8 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | catalogued as rs762984894, COSV65697419; called by mutect2, varscan2
- SYN2 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 130/433 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.903); catalogued as rs1233340757; called by muse, mutect2, varscan2
- SZT2 | c.4141C>T p.R1381* (on ENST00000634258 / NM_001365999.1; = p.R1324* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 29/333 reads (9%) | catalogued as rs777424455, COSV65168036; called by muse, mutect2
- TAF1L | c.3181G>A p.G1061R | Missense Mutation (SNP) | VAF 134/717 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.184); catalogued as rs1323461146, COSV99644964; called by muse, mutect2, varscan2
- TAMALIN | c.926G>A p.G309D | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.111); catalogued as rs1483076265; called by muse, mutect2
- TBC1D10A | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 36/493 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs368312026; called by muse, mutect2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 36/108 reads (33%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D3F | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1412577595; called by muse, mutect2, varscan2
- TBKBP1 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 22/679 reads (3%) | SIFT tolerated (0.44); PolyPhen benign (0.033); catalogued as rs1402799838; called by muse, mutect2
- TBX22 | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 136/460 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100960679; called by muse, mutect2, varscan2
- TCERG1L | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 125/402 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs201159848; called by muse, mutect2, varscan2
- TCF20 | c.4568C>T p.P1523L | Missense Mutation (SNP) | VAF 180/562 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs187417294; called by muse, mutect2, varscan2
- TCF25 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 101/282 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.769); catalogued as rs765160503; called by muse, mutect2, varscan2
- TCTEX1D1 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs142969820, COSV51077736; called by muse, mutect2, varscan2
- TCTN2 | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as rs757725319; called by muse, mutect2, varscan2
- TDRD15 | c.4682C>T p.T1561M | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.41); catalogued as rs181190937, COSV68266879; called by muse, mutect2, varscan2
- TECRL | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV101169380, COSV67086883; called by muse, mutect2, varscan2
- TENM3 | c.3448A>G p.M1150V | Missense Mutation (SNP) | VAF 120/311 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs1163113604; called by muse, mutect2, varscan2
- TENM3 | c.6569G>A p.R2190Q | Missense Mutation (SNP) | VAF 110/349 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.441); catalogued as rs1307950754; called by muse, mutect2, varscan2
- TEX14 | c.1204G>A p.E402K (on ENST00000240361 / NM_001201457.2; = p.E396K on NM_031272.5) | Missense Mutation (SNP) | VAF 81/275 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780108222, COSV53612664; called by muse, mutect2, varscan2
- TEX15 | c.3018del p.A1007Lfs*12 (on ENST00000256246; = p.A1390Lfs*12 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 29/123 reads (24%) | catalogued as rs753315680; called by mutect2, pindel, varscan2
- TEX52 | c.402dup p.T135Hfs*54 | Frame Shift Ins (INS) | VAF 160/466 reads (34%) | catalogued as rs752045113; called by mutect2, varscan2
- TFPI2 | c.195del p.Y66Tfs*24 | Frame Shift Del (DEL) | VAF 135/626 reads (22%) | catalogued as COSV55991497; called by pindel, varscan2
- TH | c.187C>T p.P63S (on ENST00000381178 / NM_199292.3; = p.P32S on NM_000360.4) | Missense Mutation (SNP) | VAF 46/393 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.917); catalogued as rs1353124114, COSV60766818, COSV60767395; called by muse, varscan2
- TIMELESS | c.3209G>A p.R1070Q | Missense Mutation (SNP) | VAF 78/318 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs200441925; called by muse, mutect2, varscan2
- TLL2 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 135/329 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs199660053, COSV100780351; called by muse, mutect2, varscan2
- TMC5 | c.863dup p.E289Rfs*3 | Frame Shift Ins (INS) | VAF 114/391 reads (29%) | catalogued as rs770349191; called by pindel, varscan2
- TMEM120A | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 42/702 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1246189271; called by muse, mutect2
- TMEM131 | c.4988C>T p.T1663M | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); catalogued as rs747091218; called by muse, mutect2, varscan2
- TMEM132E | c.32C>G p.A11G | Missense Mutation (SNP) | VAF 19/600 reads (3%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.018); catalogued as COSV100395851; called by muse, mutect2
- TMEM132E | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 179/585 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.374); catalogued as rs1437910960, COSV58700224; called by muse, mutect2, varscan2
- TMEM169 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 148/374 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199942235; called by muse, mutect2, varscan2
- TMEM198 | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 34/558 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.103); catalogued as COSV60536095; called by muse, mutect2
- TMEM231 | c.400G>A p.G134S (on ENST00000258173 / NM_001077418.3; = p.G163S on NM_001077416.2) | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.062); catalogued as rs1295426456; called by muse, mutect2, varscan2
- TMEM44 | c.599del p.P200Lfs*98 (on ENST00000392432 / NM_001166305.2; = p.P200Lfs*51 on NM_138399.5) | Frame Shift Del (DEL) | VAF 98/296 reads (33%) | catalogued as rs756927109; called by mutect2, pindel, varscan2
- TMEM72 | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 77/290 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.779); catalogued as rs201346225; called by muse, mutect2, varscan2
- TMEM81 | c.755dup p.L253Pfs*10 | Frame Shift Ins (INS) | VAF 74/274 reads (27%) | catalogued as rs767508106; called by mutect2, varscan2
- TNFAIP3 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 48/628 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs746331032, COSV52798807; called by muse, mutect2
- TNRC18 | c.1699C>T p.R567W | Missense Mutation (SNP) | VAF 471/950 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV68087421; called by muse, mutect2, varscan2
- TOB2 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 181/563 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as rs370773970, COSV59501107; called by muse, mutect2, varscan2
- TOP2A | c.4303del p.R1435Gfs*13 | Frame Shift Del (DEL) | VAF 84/235 reads (36%) | catalogued as rs758129598; called by mutect2, varscan2
- TOP2B | c.4321del p.S1441Vfs*41 (on ENST00000264331 / NM_001330700.2; = p.S1436Vfs*41 on NM_001068.3) | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as rs1293862281; called by mutect2, pindel, varscan2
- TP53BP1 | c.5438G>A p.R1813Q | Missense Mutation (SNP) | VAF 64/290 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.449); catalogued as rs368366606; called by muse, mutect2, varscan2
- TPP2 | c.2842C>T p.P948S | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65750799; called by muse, mutect2, varscan2
- TPRA1 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 148/409 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs377688619; called by muse, mutect2, varscan2
- TPRG1L | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1432606687, COSV99573255; called by muse, mutect2, varscan2
- TRAK1 | c.1201C>T p.R401C (on ENST00000327628 / NM_001349247.2; = p.R343C on NM_014965.5) | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs772082317, COSV58260703; called by muse, mutect2, varscan2
- TRBC2 | c.154G>T p.V52L | Missense Mutation (SNP) | VAF 280/538 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.067); catalogued as rs781983329; called by muse, mutect2, varscan2
- TRHDE | c.626del p.F209Sfs*9 | Frame Shift Del (DEL) | VAF 122/533 reads (23%) | catalogued as COSV53837742; called by mutect2, pindel, varscan2
- TRIO | c.8131C>T p.R2711C | Missense Mutation (SNP) | VAF 31/462 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373515068; called by muse, mutect2
- TSSK6 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 237/680 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.104); catalogued as rs1209423529, COSV53063174; called by muse, mutect2, varscan2
- TTC21A | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 89/335 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as rs753542511, COSV100087476; called by muse, mutect2, varscan2
- TTC3 | c.4674del p.K1558Nfs*13 | Frame Shift Del (DEL) | VAF 35/103 reads (34%) | catalogued as rs1388042759; called by mutect2, pindel, varscan2
- TTK | c.2560_2561del p.R854Gfs*10 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as COSV57883906; called by pindel, varscan2
- UBL7 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 132/425 reads (31%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.824); catalogued as rs374980656, COSV100795314; called by muse, mutect2, varscan2
- UBTD1 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 220/726 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.563); catalogued as rs762075717; called by muse, mutect2, varscan2
- UCP3 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 57/263 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs768018002, COSV58367980; called by muse, mutect2, varscan2
- UGDH | c.214del p.S72Lfs*18 | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | catalogued as rs765734647, COSV57097233; called by mutect2, varscan2
- UNC119 | c.326del p.P109Qfs*32 | Frame Shift Del (DEL) | VAF 72/244 reads (30%) | catalogued as rs1567611089; called by mutect2, pindel, varscan2
- USF2 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 141/427 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV55886389; called by muse, mutect2, varscan2
- USP15 | c.2585C>T p.S862L (on ENST00000280377 / NM_001351159.2; = p.S833L on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs754226149, COSV54795534; called by muse, mutect2, varscan2
- USP26 | c.1836del p.G613Afs*26 | Frame Shift Del (DEL) | VAF 25/132 reads (19%) | catalogued as rs749830910; called by mutect2, varscan2
- USP26 | c.1461del p.F487Lfs*40 | Frame Shift Del (DEL) | VAF 43/160 reads (27%) | catalogued as rs761320003; called by mutect2, varscan2
- VAT1 | c.907del p.R303Gfs*9 | Frame Shift Del (DEL) | VAF 132/577 reads (23%) | catalogued as COSV55896099; called by mutect2, pindel, varscan2
- VPS11 | c.238G>A p.D80N (on ENST00000620429; = p.D624N on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 313/439 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as rs761438612; called by muse, mutect2, varscan2
- VPS13A | c.1115del p.K372Sfs*2 | Frame Shift Del (DEL) | VAF 20/126 reads (16%) | catalogued as rs770350986; called by mutect2, varscan2
- VPS13A | c.6392C>T p.S2131L | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as rs1394368004, COSV62428775; called by muse, varscan2
- VPS18 | c.2891G>A p.R964H | Missense Mutation (SNP) | VAF 102/356 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.385); catalogued as rs772693226, COSV55029286; called by muse, mutect2, varscan2
- VWA3A | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 102/276 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs375830766; called by muse, mutect2, varscan2
- VWA5B1 | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs145193241; called by muse, mutect2, varscan2
- VWA5B2 | c.3265C>T p.R1089C | Missense Mutation (SNP) | VAF 192/758 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs747989983; called by muse, mutect2, varscan2
- WDR13 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 25/521 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.812); catalogued as rs1556993836, COSV54331732; called by muse, mutect2
- WDR19 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as rs922584346; called by muse, mutect2, varscan2
- WDR47 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.455); catalogued as rs766921575; called by muse, mutect2, varscan2
- WDR81 | c.1636G>A p.D546N | Missense Mutation (SNP) | VAF 230/638 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1437244365, COSV58482005; called by muse, varscan2
- WDR97 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 45/628 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1255542433; called by muse, mutect2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 78/239 reads (33%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WIZ | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 167/498 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.808); catalogued as rs778885934; called by muse, mutect2, varscan2
- WNK4 | c.2017C>T p.R673* | Nonsense Mutation (SNP) | VAF 125/364 reads (34%) | catalogued as rs749704694; called by muse, varscan2
- XK | c.1030A>G p.M344V | Missense Mutation (SNP) | VAF 138/401 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.048); catalogued as rs1390121391; called by muse, mutect2, varscan2
- XKR6 | c.274del p.D92Tfs*73 | Frame Shift Del (DEL) | VAF 68/219 reads (31%) | catalogued as rs1403895317; called by mutect2, varscan2
- XPO6 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 94/331 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs560769985, COSV58965096; called by muse, mutect2, varscan2
- XYLT2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 38/587 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50017423, COSV50020830; called by muse, mutect2
- YLPM1 | c.5315G>A p.R1772Q | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs774706659, COSV53109417; called by muse, mutect2, varscan2
- ZAN | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 95/411 reads (23%) | SIFT tolerated (1); PolyPhen possibly damaging (0.509); catalogued as rs1174241163, COSV61818667; called by muse, mutect2, varscan2
- ZBTB33 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs782168421, COSV104399275; called by muse, mutect2, varscan2
- ZBTB38 | c.2749C>T p.R917C | Missense Mutation (SNP) | VAF 147/408 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1357720132, COSV58540176; called by muse, mutect2, varscan2
- ZFP92 | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 265/749 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1556975003; called by muse, mutect2, varscan2
- ZFR | c.1074del p.E359Kfs*4 | Frame Shift Del (DEL) | VAF 46/176 reads (26%) | catalogued as rs751974853; called by mutect2, varscan2
- ZFR2 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 202/652 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as rs758565194; called by muse, varscan2
- ZFR2 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 222/588 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs906065213; called by muse, varscan2
- ZKSCAN3 | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 176/320 reads (55%) | catalogued as rs149951499; called by muse, mutect2, varscan2
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 74/105 reads (70%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZMYND15 | c.1650dup p.E551Rfs*33 (on ENST00000433935 / NM_001136046.3; = p.E512Rfs*33 on NM_032265.2) | Frame Shift Ins (INS) | VAF 153/490 reads (31%) | catalogued as rs1484755918; called by mutect2, pindel, varscan2
- ZNF100 | c.662C>T p.T221I | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as rs951833415; called by muse, mutect2, varscan2
- ZNF205 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 30/633 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV54620433; called by muse, mutect2
- ZNF285 | c.1240G>A p.V414I | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.036); catalogued as rs766367743, COSV58409152; called by muse, mutect2, varscan2
- ZNF433 | c.720C>A p.S240R | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.616); catalogued as COSV100794922; called by muse, mutect2, varscan2
- ZNF461 | c.729C>A p.D243E | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64454744; called by muse, mutect2
- ZNF496 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 227/706 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs765186900, COSV54176633; called by muse, varscan2
- ZNF512B | c.2054C>T p.T685M | Missense Mutation (SNP) | VAF 76/799 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as rs765675899; called by muse, mutect2
- ZNF518B | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.063); catalogued as rs139571645; called by muse, mutect2, varscan2
- ZNF528 | c.1160A>G p.D387G | Missense Mutation (SNP) | VAF 24/253 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142506057; called by muse, mutect2
- ZNF541 | c.2855G>A p.R952Q | Missense Mutation (SNP) | VAF 198/629 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs778431189; called by muse, mutect2, varscan2
- ZNF581 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 201/610 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1426035147; called by muse, mutect2, varscan2
- ZNF598 | c.2191A>G p.T731A | Missense Mutation (SNP) | VAF 142/416 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs756286175, COSV50192143; called by muse, mutect2, varscan2
- ZNF606 | c.1220C>T p.T407M | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs148677927; called by muse, mutect2, varscan2
- ZNF616 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 72/233 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV57512000, COSV57512381; called by muse, mutect2, varscan2
- ZNF682 | c.849A>C p.K283N | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV62066470; called by muse, mutect2, varscan2
- ZNF701 | c.847C>T p.R283C (on ENST00000301093; = p.R217C on NM_018260.3) | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148286783; called by muse, mutect2, varscan2
- ZNF800 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.375); catalogued as rs1329897663; called by muse, mutect2
- ZNF831 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 42/744 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs779368758; called by muse, mutect2
- ZNF835 | c.1415A>C p.K472T | Missense Mutation (SNP) | VAF 160/556 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101606367; called by muse, mutect2, varscan2
- ZNF835 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 143/632 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1162200836, COSV73379676; called by muse, mutect2, varscan2
1,087 further variants in this file (568 protein-altering or splice-affecting, 447 silent, 72 other) are not listed here.
